Surgical pathology report (de-identified scan), TCGA case TCGA-AU-3779, project TCGA-COAD (Colon Adenocarcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-AU-3779-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS

A. COLON, SIGMOID, RECTUM (RESECTION):

- INFILTRATING WELL DIFFERENTIATED ADENOCARCINOMA ARISING IN A TUBULOVILLOUS ADENOMA (4 CM)
- TUMOR IS LOCATED IN THE SIGMOID, AND EXTENDS THROUGH MUSCULARIS PROPRIA TO SURROUNDING PERICOLONIC ADIPOSE TISSUE.
- TUMOR IS 3 CM FROM CLOSEST (OPENED) MUCOSAL MARGIN OF RESECTION, EXTENDS TO 0.6 CM FROM CLOSEST SEROSAL (ANTI-MESENTERIC) SURFACE AND THE MESENTERIC RADIAL MARGIN IS 3.5 CM.
- SMOOTH MUSCLE PROLIFERATION IDENTIFIED IN SEROSAL ADHESIONS CONSISTENT WITH PARTIAL MYOMECTOMY AS DESCRIBED INTRA-OPERATIVELY.
- ADDITIONAL FINDINGS ARE NOTED IN NON-NEOPLASTIC MUCOSA INCLUDING DIVERTICULAR DISEASE WITH RUPTURED DIVERTICULITIS AND ASSOCIATED SOFT TISSUE INFLAMMATION AND FIBROSIS, AS WELL AS INCIDENTAL HYPERPLASTIC POLYP (0.1 CM).
- ALL SURGICAL MARGINS AND TWENTY-ONE REGIONAL LYMPH NODES, NEGATIVE FOR TUMOR.

PATHOLOGIC STAGE: pT3 N0 MX

B. DONUTS (RESECTION): HISTOLOGICALLY UNREMARKABLE SEGMENTS OF LARGE INTESTINE.

SYNOPTIC REPORT

SYNOPTIC REPORT: COLON AND RECTUM
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: PARTIAL COLECTOMY

SPECIMEN SIZE: 16 CM

TUMOR SITE: SIGMOID

TUMOR SIZE: 4 CM

HISTOLOGIC TYPE: ADENOCARCINOMA

HISTOLOGIC GRADE: 1

EXTENT OF INVASION: THROUGH MUSCULAR PROPRIA

f,,, (IF THROUGH MUSCULARIS PROPRIA, DISTANCE BEYOND:) 0.1 CM

f,,, OTHER ORGANS INVOLVED/VISCERAL PERITONEUM (SPECIFY): NONE

MARGINS:

f,,, PROXIMAL: UNINVOLVED

f,,, DISTAL: UNINVOLVED

f,,, RADIAL MESENTERIC: UNINVOLVED (3.5 CM)

f,,, (IF MARGINS UNINVOLVED, DISTANCE TO CLOSEST MARGIN:) 0.6 CM FROM
SEROSAL ANTI-MESENTERIC

[page 2 of 2]
LYMPHATIC INVOLVEMENT (PRESENT/ABSENT): ABSENT

VENOUS (LARGE VESSEL) INVOLVEMENT (PRESENT/ABSENT): ABSENT

LYMPH NODES:

f,,, #INVOLVED/#EXAMINED: 0/21

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT3 NO MX

Source: NCI Genomic Data Commons file 64e9c956-5ab5-46f3-b876-fbdcfd91104a (TCGA-AU-3779.8704AD3A-A420-41E3-A71E-4CA49DD90D32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).